ORGANOID case 61 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/670dc6a3-d40a-4283-8e99-c847d33b5099

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (2 samples)
- Samples S101, S158 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Normal; Specimen type: 3D Organoid.
